Gene-level copy-number profile of tumor specimen TCGA-K4-A5RH-01A from TCGA case TCGA-K4-A5RH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.3 years (25,305 days).
Specimen TCGA-K4-A5RH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d5f8227a-d0b2-4dde-ba61-97ad58f238b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K4-A5RH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/673e709b-24b1-41a6-a496-b6604e1359fe

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 806; copy number 2: 2,227; copy number 3: 23,378; copy number 4: 15,528; copy number 5: 8,677; copy number 6: 6,115; copy number 7: 750; copy number 8: 142; copy number 9: 273; copy number 10: 437; copy number 11: 67; copy number 12: 739; copy number 13: 518; copy number 15: 107; copy number 17: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K4-A5RH-01A-11D-A30D-01): tumor purity 0.48, ploidy 2.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:217,693,895–217,761,291, 2 genes: AC010886.1, RPL7L1P9.
- chr17:30,970,984–30,999,911, 1 gene (within-gene range 0–2): RNF135.
- chr17:30,978,610–31,637,543, 25 genes (within-gene range 0–2): AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B, AC007923.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,014 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,840,962–149,048,286, 50 genes, copy number 8 (within-gene range 5–8): AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3, LINC01138, LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6, RNVU1-1, RNU1-155P, MIR6077, RNVU1-2, AC245100.4, RNVU1-3, AC245100.2, AC245100.8, AC245100.7, PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2.
- chr1:151,944,890–156,766,925, 283 genes, copy number 7–12 (broad region; genes not listed).
- chr1:156,768,105–156,769,233, 1 gene, copy number 7: AL590666.5.
- chr1:158,831,351–169,586,588, 304 genes, copy number 9–17 (within-gene range 4–17) (broad region; genes not listed).
- chr1:244,969,705–247,896,531, 86 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:6,770,001–7,741,533, 1 gene, copy number 8 (within-gene range 6–8): GRM7.
- chr3:7,241,916–11,557,665, 91 genes, copy number 8 (broad region; genes not listed).
- chr3:87,630,301–94,938,024, 39 genes, copy number 7: PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1.
- chr5:58,198–45,895,970, 710 genes, copy number 12 (broad region; genes not listed).
- chr7:70,972–1,509,427, 45 genes, copy number 7: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1.
- chr8:73,991,392–76,683,308, 36 genes, copy number 7: LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1.
- chr8:91,909,738–92,879,502, 14 genes, copy number 7: PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2.
- chr8:141,968,091–145,066,685, 170 genes, copy number 7 (broad region; genes not listed).
- chr9:107,420,191–112,039,143, 71 genes, copy number 10–12 (broad region; genes not listed).
- chr10:57,304,479–67,696,195, 91 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr14:18,333,726–24,052,555, 416 genes, copy number 13 (broad region; genes not listed).
- chr17:15,014,805–15,106,187, 4 genes, copy number 9: AC005772.1, CDRT7, AC005772.2, CDRT8.
- chr17:16,893,198–17,591,708, 30 genes, copy number 7 (within-gene range 4–7): AL353996.1, TBC1D27P, TNFRSF13B, AC104024.1, LINC02090, AC104024.2, AC104024.3, AC104024.4, MPRIP, MPRIP-AS1, AC055811.1, RNU6-767P, RN7SL775P, AC055811.4, PLD6, AC055811.2, FLCN, AC055811.3, ACTG1P24, COPS3, NT5M, RPL13P12, AC073621.1, TSEN15P1, Y_RNA, MED9, RASD1, AC020558.6, PEMT, AC020558.2.
- chr17:18,697,998–19,214,045, 37 genes, copy number 9: TRIM16L, AC026271.3, FBXW10, TVP23B, AC107982.3, AC107982.1, PRPSAP2, RN7SL627P, AC107982.2, AC090286.3, AC090286.2, SLC5A10, AC090286.1, FAM83G, AC090286.4, GRAP, AC003957.1, SNORD3B-1, SNORD3B-2, AC007952.3, KYNUP2, AC007952.7, AC007952.2, AC007952.4, SNORD3D, SNORD3D, GRAPL, AC007952.6, AC007952.9, AC007952.1, AC007952.5, AC007952.8, KYNUP1, SNORD3A, SNORD3C, AC106017.1, KYNUP3.
- chr17:19,219,143–19,222,527, 1 gene, copy number 9: AC106017.2.
- chr18:47,390–15,330,282, 376 genes, copy number 10 (broad region; genes not listed).
- chr19:39,196,964–39,555,356, 29 genes, copy number 7: NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2.
- chr22:18,873,543–21,081,018, 129 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 806. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
